Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5174, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5174-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

TCGA - BP - 5174

Specimens Submitted:

1: SP: Left renal tumor

2: SP: Deep margin #2

DIAGNOSIS:

- 1) KIDNEY, LEFT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 1.9 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- THE SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) KIDNEY, DEEP MARGIN #2; EXCISION:
- BENIGN RENAL PARENCHYMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled, "Left renal tumor (stitch marks deep margin #1)". It consists of a 4.0 x 2.5 x 1.1 cm portion of kidney with a stitch marking the deep margin. The deep margin is inked black and the specimen is serially sectioned to reveal a 1.9 x 1.5 x 1.5 cm circumscribed, bright yellow, focally hemorrhagic nodule that comes within 1 mm of the deep inked margin. A representative section of the tumor with margin is submitted for frozen section diagnosis. A portion is also submitted for TPS. The uninvolved kidney is tan-brown and homogenous. The entire tumor and representative sections of uninvolved kidney are submitted.

Summary of Sections:

FSC - frozen section control

T - tumor

NL - uninvolved kidney

2) The specimen is received fresh for frozen section labeled, "Deep margin #2". The specimen is of a single pink-tan soft tissue fragment. Submitted in toto.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of sections:
FSC-frozen section control.

Summary of Sections:

Part 1: SP: Left renal tumor

Block	Sect. Site	PCs
1	FSC	1
1	NL	1
3	T	3

Part 2: SP: Deep margin #2

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: STITCHED MARGIN NEGATIVE FOR TUMOR
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: NO TUMOR SEEN
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 018f0ddd-488c-427c-a227-5b0482183006 (TCGA-BP-5174.3CA5952B-4286-4703-9E27-02019B71599E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).